Somatic mutation profile of tumor specimen TCGA-D7-A4YX-01A (aliquot TCGA-D7-A4YX-01A-11D-A25D-08) from TCGA case TCGA-D7-A4YX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.7 years (23,249 days).
Specimen TCGA-D7-A4YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71fbbfa3-a354-44b3-aab5-f3609f619ff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4YX-10A (Blood Derived Normal), aliquot TCGA-D7-A4YX-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aabc901-3191-4e42-a24c-c54d5b62aa8b

The open-access MAF lists 85 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, Intron 2, In Frame Del 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCB5 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs767933970, COSV68856671; called by muse, mutect2
- ADAMTS15 | c.2020G>C p.V674L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs764503203, COSV54504809; called by muse, mutect2, varscan2
- ARHGEF10 | c.3488C>T p.S1163L (on ENST00000398564; = p.S1138L on NM_014629.4) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs145686019; called by muse, mutect2, varscan2
- ARHGEF10L | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 182/312 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.169); catalogued as COSV63418801; called by muse, mutect2, varscan2
- BHLHE22 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV58861582; called by muse, mutect2, varscan2
- CACNA1D | c.5837G>A p.R1946H (on ENST00000350061 / NM_001128840.3; = p.R1966H on NM_000720.4) | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.715); catalogued as rs150366975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.362C>T p.S121F (on ENST00000341926; = p.S204F on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57784965; called by muse, mutect2, varscan2
- CCDC178 | c.2388+1G>T p.X796_splice (on ENST00000383096 / NM_001105528.3; = p.X758_splice on NM_198995.3) | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV55769728; called by muse, mutect2, varscan2
- CD163L1 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58014589; called by muse, mutect2, varscan2
- CLDN17 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54522747; called by muse, mutect2, varscan2
- CMYA5 | c.10957G>A p.V3653I | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs1371909044, COSV71405386; called by muse, mutect2, varscan2
- CSRNP3 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58777541; called by muse, mutect2, varscan2
- DHX58 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs782702291, COSV52425421, COSV52426702; called by muse, mutect2, varscan2
- DRAXIN | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761284008, COSV53841764, COSV99610574; called by muse, mutect2, varscan2
- E2F7 | c.2722G>A p.G908S | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59739053; called by muse, mutect2, varscan2
- EPHB4 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1244578543, COSV62268620; called by muse, mutect2, varscan2
- FSIP2 | c.19337C>A p.T6446K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV100557069; called by muse, mutect2, varscan2
- GALP | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752811117, COSV100628088, COSV61999717; called by muse, mutect2, varscan2
- GATA2 | c.1267_1269del p.E423del | In Frame Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs1278525191; called by mutect2, pindel, varscan2
- GRAMD1B | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | catalogued as COSV59203004; called by muse, mutect2, varscan2
- IARS2 | c.2909G>T p.R970L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV56959102; called by muse, mutect2, varscan2
- IWS1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV54867862; called by muse, mutect2, varscan2
- KCNG4 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs371318548; called by muse, mutect2, varscan2
- KIAA1549L | c.5330C>A p.S1777Y (on ENST00000321505; = p.S2074Y on NM_012194.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100381694, COSV58586399; called by muse, mutect2, varscan2
- KIF3C | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs145081324; called by muse, mutect2, varscan2
- LAMA1 | c.6493G>C p.D2165H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370881774, COSV67535487, COSV67544573; called by muse, mutect2, varscan2
- NCALD | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV55272086; called by muse, mutect2, varscan2
- NEK10 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); catalogued as COSV55357618; called by muse, mutect2, varscan2
- NTNG1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53968696; called by muse, mutect2, varscan2
- OR10K2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs762306649, COSV59220549; called by muse, mutect2, varscan2
- OR2T12 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58777180; called by muse, mutect2, varscan2
- OTOF | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs200972155; called by muse, mutect2, varscan2
- PARM1 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56652472; called by muse, mutect2, varscan2
- PCDH10 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092050; called by muse, mutect2, varscan2
- PCNX1 | c.5126C>T p.T1709M | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs776355164, COSV53093028; called by muse, mutect2, varscan2
- PGLYRP3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); catalogued as rs369979237; called by muse, mutect2, varscan2
- PRSS55 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs1407837010, COSV60808005; called by muse, mutect2, varscan2
- RFC3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761845498, COSV66296589; called by muse, mutect2, varscan2
- RNF123 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs1018352551, COSV59686354; called by muse, mutect2, varscan2
- RNF157 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201739916, COSV53943416; called by muse, mutect2, varscan2
- RSPH10B | c.1415-2A>G p.X472_splice | Splice Site (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100521341; called by muse, mutect2
- SERPING1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM117773, COSV53542235; called by muse, mutect2, varscan2
- SHROOM4 | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as rs143812034, COSV56788003; called by muse, mutect2, varscan2
- SI | c.4518C>A p.D1506E | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs1179410069, COSV52272233; called by muse, mutect2, varscan2
- SLC24A4 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs370133202; called by muse, mutect2, varscan2
- SPTA1 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV63751847; called by muse, mutect2, varscan2
- TAF1L | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as rs1438154815, COSV54260601, COSV54260696; called by muse, mutect2, varscan2
- TF | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs377691845; called by muse, mutect2, varscan2
- THBS2 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.298); catalogued as COSV64678350; called by muse, mutect2, varscan2
- TNFRSF1A | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV50599457; called by muse, mutect2, varscan2
- TP53BP2 | c.1018C>T p.P340S (on ENST00000343537 / NM_001031685.3; = p.P211S on NM_005426.2) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs1426341667, COSV59067818; called by muse, mutect2, varscan2
- TRIM41 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as rs936135686, COSV59318582; called by muse, mutect2
- TRIO | c.881A>T p.K294I | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as COSV60082059; called by muse, mutect2, varscan2
- VEGFD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52909448; called by muse, mutect2, varscan2
- WDR44 | c.2123T>C p.V708A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54162574; called by muse, mutect2, varscan2
- WDR64 | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs139639842; called by muse, mutect2, varscan2
- ARID1A | c.4472_4479del p.V1491Afs*9 | Frame Shift Del (DEL) | VAF 81/169 reads (48%) | called by mutect2, pindel, varscan2
- FAR2 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MACC1 | c.1431_1432del p.H477Qfs*7 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by pindel, varscan2
- ADAMTS13 | c.2685C>T p.H895= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs370669534; called by muse, mutect2, varscan2
- ADO | c.375C>T p.Y125= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1195494047, COSV65677809; called by muse, mutect2, varscan2
- AL121899.2 | c.1362C>T p.D454= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs776078400, COSV67350353; called by muse, mutect2, varscan2
- CELF1 | c.852C>G p.L284= (on ENST00000358597 / NM_001376422.1; = p.L280= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV60111444; called by muse, mutect2, varscan2
- CSMD1 | c.9363T>C p.S3121= (on ENST00000520002; = p.S3120= on NM_033225.6) | Silent (SNP) | VAF 69/344 reads (20%) | catalogued as COSV59310607; called by muse, mutect2, varscan2
- CTNNB1 | c.396G>A p.L132= | Silent (SNP) | VAF 517/571 reads (91%) | catalogued as rs778138109, COSV62697481; called by muse, varscan2
- CTNNB1 | c.468G>C p.L156= | Silent (SNP) | VAF 474/522 reads (91%) | catalogued as rs745411917, COSV62697485; called by muse, varscan2
- FBN1 | c.2919C>T p.G973= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV57314581; called by muse, mutect2, varscan2
- INTS5 | c.1230G>A p.L410= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1203881180, COSV57950346; called by muse, mutect2, varscan2
- INTS8 | c.2943A>G p.R981= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV57375818; called by muse, mutect2, varscan2
- MATN1 | c.1302G>A p.T434= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs573315394, COSV65650449; called by muse, mutect2, varscan2
- OR5T1 | c.351T>C p.C117= | Silent (SNP) | VAF 56/193 reads (29%) | catalogued as rs556330952, COSV57302471; called by muse, mutect2, varscan2
- PCDH8 | c.573C>T p.G191= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58812124; called by muse, mutect2
- PDE2A | c.1440C>T p.D480= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57805411; called by muse, mutect2, varscan2
- PHF20L1 | c.468C>T p.I156= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs755817701; called by muse, varscan2
- PHGDH | c.195C>T p.N65= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as rs771208719, COSV65570750; called by muse, mutect2, varscan2
- PRPF6 | c.1491C>T p.N497= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs530473195, COSV53869042; called by muse, mutect2
- RYR1 | c.6493C>T p.L2165= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV62094836; called by muse, mutect2, varscan2
- SLCO3A1 | c.333C>T p.C111= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs760273166, COSV59228734; called by muse, mutect2, varscan2
- TFDP1 | c.72C>T p.P24= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs144432965; called by muse, mutect2, varscan2
- USP22 | c.1134C>T p.S378= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs773331562, COSV54946296; called by muse, mutect2, varscan2
- ZNF648 | c.1497C>T p.S499= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs757239006, COSV60570406; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532285 T>A | 5'Flank (SNP) | VAF 12/35 reads (34%) | catalogued as COSV73219676; called by muse, mutect2, varscan2
- CDKN2A | c.150+141T>C | Intron (SNP) | VAF 98/348 reads (28%) | called by muse, varscan2
- MICAL3 | c.2242-825A>G | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs1379225489; called by muse, mutect2
